CCDI case PBCAFP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/74e6b33f-2cad-4542-b739-49f88c052bda

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 14.2 years (5,189 days).

Biospecimens (3 samples)
- Sample 0DM8U8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM8W0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DM8W3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
